Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6670, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6670-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

ADDENDED

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Temporal lobe: RECURRENT OLIGODENDROGLIOMA. SEE DIAGNOSIS FOR SPECIMEN #2
2. Insula: aNAPLASTIC OLIGODENDROGLIOMA, WHO GRADE iii. SEE MICROSCOPIC DESCRIPTION. SEE COMMENT.

Comment:

The patient has a history of previous oligodendroglioma. Neither the patient's previous pathology slides nor pathology report was available for review at the time of case signout.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Aperio

Ki67

Percent : 5.8%

Cells counted : 32,882 cells

This test was performed by [REDACTED] in conjunction with the [REDACTED]-computer

[page 2 of 4]
assisted image analysis.

[REDACTED]

Addendum

IMMUNOHISTOCHEMICAL STAINS

GFAP: POSITIVE STAINING OF MANY TUMOR CELLS (SLIDE 2B)

P53: POSITIVE STAINING OF SCATTERED TUMOR CELL NUCLEI IN HYPERCELLULAR AREAS OF THE TUMOR (SLIDE 2B).

[REDACTED]

Microscopic Description:

Most of specimen #1 ("temporal lobe") shows a low grade oligodendroglioma. In contrast to specimen #1, specimen #2 contains areas of increased cellularity, focal brisk mitotic rate, cytologic atypic and focal microvascular proliferation. The Ki67 proliferation index of the tumor in the hypercellular areas of specimen #2 ranges from 4% to 9% with an average of 5.8 % (32,882 cells counted). The histologic features identified in specimen#2 are sufficient for the diagnosis of Anaplastic Oligodendroglioma, WHO grade III. The features of anaplastic oligodendroglioma are best identified on slide 2B. Case reviewed in conference with [REDACTED] [REDACTED]

A separate report with the results of FISH analysis of 1p19q status will be issued.

Frozen Section Diagnosis:

1. Temporal lobe: Infiltrative glioma
2. Insula: Infiltrative glioma. Cellularity greater than #1.
- No obvious anaplastic features-

Frozen section diagnoses by [REDACTED] [REDACTED]

[page 3 of 4]
Clinical History and Diagnosis:

Right temporal brain tumor. History of previous biopsy of Oligodendroglioma, "low grade".

Source of Specimen:

- 1: Temporal lobe
- 2: Insula

Gross Description:

- 1. Temporal lobe: Received fresh for frozen section in a specimen container labeled with the patient's name and "#1 temporal lobe" is a 4 x 3.5 x 1 centimeter fragment of tan-yellow soft tissue. A representative sample comprising about 5% is frozen for intraoperative consultation and touch prep were done. The entire specimen is submitted as follows:
- A. Frozen section control
- B.-F. Remainder of specimen

- 2. Insula: Received fresh for frozen section a specimen container labeled with the patient's name and "2 insula" are multiple pieces of tan-pink soft tissue measuring 3.0 x 2.8 x 0.5 cm in aggregate. A representative sample is used for touch preps and frozen for intraoperative consultation. The entire specimen is admitted as follows:
- A. Frozen section control
- B. Remainder of specimen

Histology Laboratory
H&E

Part 2: Insula
19q - FISH
1p - FISH
GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)
KI 67 (Aperio)
MOLECULAR H&E
NEU - N
P 53

[page 4 of 4]
Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED] et.al. Applied [REDACTED]

2. Pathway Her-2/neu (4B5) ([REDACTED] monoclonal) - Formalin-fixed, paraffin embedded tissue. [REDACTED]

Interpretation follows the manufacturer's recommendation.

3. EGFR (3C6) ([REDACTED] [REDACTED] Formalin-fixed, paraffin embedded tissue. [REDACTED] Kit.

4. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the [REDACTED].

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 715341b7-7d2f-4c42-adae-6d98d301d719 (TCGA-CS-6670.925AEB6B-7ED0-40B5-B2BB-52EFBDAB0748.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).